CPTAC case C760878 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/1f36d950-331b-4746-97a4-94cd6f56aa55

Demographics
Sex at birth: male; Age at index: 69 years; Vital status: Dead; Days to death: 590 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Frontal lobe; Site of resection or biopsy: Frontal lobe; Tumor grade: G3; Residual disease: R2; Last known disease status: With tumor; Days to last known disease status: 590 days (1.6 years); Progression or recurrence: yes; Days to recurrence: 550 days (1.5 years); Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Cigarettes per day: 0; Alcohol history: No.

Biospecimens (9 samples)
- Samples 1104791, 1105254, SM-JU335 (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples 1104803, 1105268, SM-JU33H (3 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 1105278: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample C760878-TP: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Cortex; Biospecimen laterality: Right; Preservation method: Snap Frozen.
- Sample C760878-TR1: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Biospecimen laterality: Bilateral; Preservation method: Snap Frozen.
